Somatic mutation profile of cancer-model specimen HCM-CSHL-0094-C25-85B (3D Organoid; aliquot HCM-CSHL-0094-C25-85B-01D-A78M-36), derived from the primary tumor of HCMI case HCM-CSHL-0094-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.5 years (22,468 days).
Specimen HCM-CSHL-0094-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1901d805-005f-4b3b-90d2-d23cad4eede5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0094-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0094-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81efc793-14af-48c1-9ebe-0c658836dc12

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Intron 3, 5'Flank 1, Frame Shift Ins 1, Translation Start Site 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 168/169 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 246/246 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 110/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753831464, COSV51941487; ClinVar: benign; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 121/244 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DCDC1 | c.4187C>T p.T1396M (on ENST00000597505 / NM_001367979.1; = p.T503M on NM_020869.3) | Missense Mutation (SNP) | VAF 98/279 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs563373193, COSV58004873; called by muse, mutect2, varscan2
- EIF2AK4 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV55471934; called by muse, varscan2
- FZD10 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV57473678, COSV99969588; called by muse, mutect2, varscan2
- LNX1 | c.1393C>T p.R465W (on ENST00000263925 / NM_001126328.3; = p.R369W on NM_032622.2) | Missense Mutation (SNP) | VAF 102/142 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs753035872, COSV55784766; called by muse, mutect2, varscan2
- MYH4 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.44); catalogued as rs185824725; called by muse, mutect2, varscan2
- PCDH18 | c.981A>T p.Q327H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61266332, COSV61268397; called by muse, mutect2, varscan2
- PCDHA3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 288/290 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.435); catalogued as COSV100793689; called by muse, mutect2, varscan2
- PDCD6IP | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs752951471; called by muse, mutect2, varscan2
- PLCG2 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368889160; called by muse, mutect2, varscan2
- PRKCE | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 115/352 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100077197; called by muse, mutect2, varscan2
- PTCH2 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.552); catalogued as rs377325413; called by muse, mutect2, varscan2
- RTL3 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 77/393 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58183628; called by muse, mutect2, varscan2
- SYNE1 | c.12122G>A p.R4041Q (on ENST00000367255 / NM_182961.4; = p.R3970Q on NM_033071.3) | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as rs771461121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.3307G>A p.V1103M (on ENST00000367255 / NM_182961.4; = p.V1110M on NM_033071.3) | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1229856716, COSV54929914; called by muse, mutect2, varscan2
- TRIM48 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV70163820; called by muse, mutect2
- TUT1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 114/206 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs746824330; called by muse, mutect2, varscan2
- ZP3 | c.532G>A p.E178K (on ENST00000394857 / NM_001110354.2; = p.E127K on NM_007155.6) | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV60631483; called by muse, mutect2
- ACSBG1 | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, varscan2
- CDKN2A | c.379dup p.A127Gfs*15 | Frame Shift Ins (INS) | VAF 323/454 reads (71%) | called by mutect2, pindel, varscan2
- CNTN2 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.7488T>G p.C2496W | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOSC7 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 183/330 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EXOSC8 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 97/213 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- HOXA4 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IER5 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 186/260 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MBD6 | c.2873+1G>T p.X958_splice | Splice Site (SNP) | VAF 154/247 reads (62%) | called by muse, mutect2, varscan2
- PAQR5 | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 125/195 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PIAS1 | c.436T>A p.L146I | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRAMEF15 | c.1017T>A p.S339R | Missense Mutation (SNP) | VAF 243/814 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SCN9A | c.4322T>C p.I1441T (on ENST00000303354; = p.I1430T on NM_002977.3) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SEMA6D | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR1 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 164/164 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ACTR3C | c.111A>G p.T37= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs916981079; called by muse, mutect2
- AGPAT1 | c.423G>A p.L141= | Silent (SNP) | VAF 438/450 reads (97%) | catalogued as rs780934272; called by muse, mutect2, varscan2
- IRGC | c.1185C>T p.D395= | Silent (SNP) | VAF 159/235 reads (68%) | catalogued as rs142781236; called by muse, mutect2, varscan2
- MKRN3 | c.456G>A p.P152= | Silent (SNP) | VAF 96/333 reads (29%) | catalogued as rs536725835, COSV100091899; called by muse, mutect2, varscan2
- MUC12 | c.9231T>G p.L3077= (on ENST00000379442; = p.L2934= on NM_001164462.1) | Silent (SNP) | VAF 247/2831 reads (9%) | called by muse, mutect2, varscan2
- NLRP4 | c.657C>A p.I219= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as rs754739238, COSV56711965; called by muse, mutect2, varscan2
- OR5D16 | c.669C>T p.I223= | Silent (SNP) | VAF 62/207 reads (30%) | called by muse, mutect2, varscan2
- PCDH15 | c.4950G>A p.S1650= | Silent (SNP) | VAF 45/344 reads (13%) | catalogued as rs755469136; called by muse, mutect2, varscan2
- RMC1 | c.831G>C p.V277= | Silent (SNP) | VAF 48/48 reads (100%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1278C>T p.G426= (on ENST00000621492; = p.G392= on NM_025248.3) | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- TNRC18 | c.1581C>T p.A527= | Silent (SNP) | VAF 239/457 reads (52%) | catalogued as rs1221834058; called by muse, mutect2, varscan2
- ZWINT | c.741G>A p.Q247= | Silent (SNP) | VAF 21/176 reads (12%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915952 G>A | 5'Flank (SNP) | VAF 86/153 reads (56%) | called by muse, mutect2, varscan2
- ATXN7 | c.2661+1151C>T | Intron (SNP) | VAF 97/164 reads (59%) | called by muse, mutect2, varscan2
- CD22 | c.-6G>A | 5'UTR (SNP) | VAF 68/265 reads (26%) | catalogued as rs374673200; called by muse, mutect2, varscan2
- FTCD | c.1261-39T>C | Intron (SNP) | VAF 129/218 reads (59%) | called by muse, mutect2, varscan2
- SLC2A11 | c.537-272C>T | Intron (SNP) | VAF 77/134 reads (57%) | catalogued as rs756171416; called by muse, mutect2, varscan2
